Gene-level copy-number profile of tumor specimen C3N-02010-03 from CPTAC case C3N-02010, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.3 years (22,742 days).
Specimen C3N-02010-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 65c539d9-39e7-4f8b-bfa6-4a4603c5dda9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02010-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/8d557487-55fa-422e-a218-789a140e1618

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 154; copy number 1: 11,974; copy number 2: 43,247; copy number 3: 2,490; copy number 4: 421; copy number 5: 97; copy number 6: 3; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 154 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:120,462,511–120,706,789, 1 gene (within-gene range 0–1): AL096854.1.
- chr6:120,686,621–120,781,512, 2 genes: RNA5SP215, COX6A1P3.
- chr9:20,331,446–21,142,145, 16 genes: AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1.
- chr9:21,178,589–22,455,740, 48 genes: IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:24,542,952–32,293,692, 60 genes: IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281.
- chr9:60,914,407–61,231,863, 10 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1.
- chr16:33,827,214–33,827,661, 1 gene: IGHV3OR16-13.
- chr18:50,879,080–51,643,939, 12 genes: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 103 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,267,926–41,654,244, 12 genes, copy number 5: TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI.
- chr6:42,696,598–43,852,333, 61 genes, copy number 5 (broad region; genes not listed).
- chr11:44,629,357–45,513,802, 16 genes, copy number 5 (within-gene range 4–5): RPL34P22, AC104010.1, LINC02704, TSPAN18-AS1, TSPAN18, TP53I11, LINC02685, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1.
- chr16:33,844,784–33,875,468, 6 genes, copy number 6–7: AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3.
- chr20:22,220,554–22,607,517, 8 genes, copy number 5: AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF.

Autosomal genes at a single copy (total copy number 1): 9,654. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
